Somatic mutation profile of tumor specimen 0E1BNR from CCDI case PBCVKW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1BNR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0cc2804-4535-4c99-a236-82af01119873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1BOK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6312720a-08c1-4078-9f20-295900dbe0c0

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCPG1 | c.1652G>T p.R551I | Missense Mutation (SNP) | VAF 158/612 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs762463706, COSV51241191; called by muse, varscan2
- ALK | c.3832T>G p.Y1278D | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- VN1R2 | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, varscan2
- BCORL1 | c.5079G>A p.E1693= | Silent (SNP) | VAF 78/220 reads (35%) | called by muse, varscan2
